Somatic mutation profile of tumor specimen TCGA-DJ-A2PP-01A (aliquot TCGA-DJ-A2PP-01A-11D-A19J-08) from TCGA case TCGA-DJ-A2PP, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 47.7 years (17,410 days).
Specimen TCGA-DJ-A2PP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f427a3f9-a4b4-4b04-8c07-893931705358.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A2PP-10A (Blood Derived Normal), aliquot TCGA-DJ-A2PP-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8247a4f-8dd4-4ccd-898e-ac2eac20f410

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, Splice Region 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 85/204 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CAPN13 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 72/200 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs771712940, COSV54428881; called by muse, mutect2, varscan2
- ERCC6 | c.968A>G p.K323R | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV63389062; called by muse, mutect2, varscan2
- PCDHGA4 | c.1795C>A p.P599T | Missense Mutation (SNP) | VAF 35/390 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53910279, COSV53927635; called by muse, mutect2
- PGLYRP4 | c.354C>T p.N118= | Splice Region (SNP) | VAF 33/93 reads (35%) | catalogued as rs774296725, COSV62834989; called by muse, mutect2, varscan2
- PIGZ | c.1264C>T p.L422F | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.919); catalogued as COSV53013391; called by muse, mutect2, varscan2
- POLR3B | c.3340T>A p.F1114I | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.26); catalogued as COSV57277857; called by muse, mutect2, varscan2
- PTPRS | c.1229A>G p.Q410R | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.401); catalogued as COSV53616256; called by muse, mutect2, varscan2
- SLC12A4 | c.2221G>A p.E741K | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs771589129, COSV50452567; called by muse, mutect2, varscan2
- TG | c.4600A>G p.K1534E | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.024); catalogued as COSV55071991; called by muse, mutect2
- TULP4 | c.1628C>T p.P543L | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as rs1161215196, COSV65574217; called by muse, mutect2
- HEATR9 | c.940-1G>A p.X314_splice | Splice Site (SNP) | VAF 11/36 reads (31%) | called by muse, mutect2
- ANKMY2 | c.798C>T p.I266= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV61011411; called by muse, mutect2, varscan2
- LYST | c.6921A>G p.L2307= | Silent (SNP) | VAF 32/90 reads (36%) | catalogued as rs544394700, COSV67705772; called by muse, mutect2, varscan2
- VPS50 | c.90G>A p.R30= | Silent (SNP) | VAF 39/121 reads (32%) | catalogued as COSV52494000; called by muse, mutect2, varscan2
- CPLANE1 | chr5:37168905 T>C | 3'Flank (SNP) | VAF 30/160 reads (19%) | catalogued as COSV57057064; called by muse, varscan2
